Surgical pathology report (de-identified scan), TCGA case TCGA-2V-A95S, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of California San Diego, specimen TCGA-2V-A95S-01A (Primary Tumor).

[page 1 of 5]
ICD-0-3
Carcinoma, hepatocellular 8770/3
Site: Liver c22.0
9/11/14

SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS:

A: Bile duct, distal margin, excision

-Positive for detached fragments of hepatocellular carcinoma.

B: Bile duct, distal margin #2, excision

-Negative for carcinoma.

C: Bone, xiphoid, excision

*-Bone with trilineage hematopoiesis.
-Unremarkable cartilage and adipose tissue.
-Negative for carcinoma.*

D: Gallbladder, cholecystectomy

*-Gallbladder with chronic cholecystitis and focal intestinal metaplasia.
-Negative for carcinoma.*

E: Liver, right hepatic lobe, partial hepatectomy

-Hepatocellular carcinoma, poorly differentiated.

[page 2 of 5]
- Margins negative for carcinoma (see Comment).**
- Background liver with incomplete cirrhosis (stage 5 out of 6) and hemosiderosis (patchy positive 2+/4 staining in hepatocytes and 3+/4 staining in Kupffer cells).**
- Pathologic Stage: pT2 NX (see Comment and Synoptic Report).**

F: Vein, portal bifurcation, excision

- Unremarkable vein and soft tissue.**
- Negative for carcinoma.**

COMMENT: The tumor consists of a poorly differentiated carcinoma composed of malignant cells with coarse or vesicular chromatin, occasional prominent nucleoli, and a moderate amount of amphiphilic cytoplasm arranged in dense sheets or pseudoglandular structures with associated prominent interspersed inflammation. There are scattered multinucleated cells. In part E, immunohistochemical stains were performed (block E10) and demonstrate that the tumor is strongly positive for glypican 3, and negative for CK7, CK20, and hepatocyte specific antigen (Hep-Par1). The histomorphology and immunohistochemical profile is consistent with a poorly differentiated hepatocellular carcinoma. The previous outside biopsy was reviewed in conjunction with the current case and the tumors are histologically similar. The tumor closely approaches (less than 0.1 cm), but does not involve, the parenchymal margin of resection. This case was intradepartmentally reviewed on

Hepatocellular Carcinoma Synoptic Report: Hepatic Resection

Specimen: Liver and gallbladder

Procedure: Partial hepatectomy

Tumor Size: Greatest dimension: 7.5 cm
Additional dimensions: 7.0 x 4.0 cm

Tumor Focality: Solitary

Histologic Type: Hepatocellular carcinoma

Histologic Grade: GIII: Poorly differentiated

Tumor Extension: Tumor confined to liver

Margins: Parenchymal Margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: <1.0 mm

Other Margin: Bile duct margin uninvolved by invasive carcinoma

Lymphovascular Invasion:

Macroscopic Venous (Large Vessel) Invasion (V): Not identified

Microscopic (Small Vessel) Invasion (L): Present

[page 3 of 5]
Perineural Invasion: Not identified

Pathologic Staging (pTNM):

Primary Tumor (pT): pT2: Solitary tumor with vascular invasion
Regional Lymph Nodes (pN): pNX: Cannot be assessed
Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: The background liver shows incomplete cirrhosis with marked portal-portal and portal-central bridging and occasional nodules (stage 5/6, confirmed on trichrome stain).

Standard liver reporting items:

-Adequacy: Partial hepatectomy specimen
-Steatosis: < 1%
-Stainable Iron: Patchy 2+/4 positivity in hepatocytes and patchy 3+/4 positivity in Kupffer cells
-PASD: No periportal eosinophilic globules
-Reticulin: Reticulin stain examined and contributory

SPECIAL STAINS/PROCEDURES: Special stains and/or procedures were used in the final interpretation. All stains were performed with appropriate positive and negative controls.

The immunostain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration, although such approval is not required for analyte-specific reagents of this type. The FDA has determined that such clearance is not necessary. This laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. Pursuant to the requirements of CLIA, this laboratory has established and verified the test's relevant performance specifications. Data collected for the verification process are available upon request.

SPECIMEN(S) SUBMITTED:

A: distal margin bile duct
B: distal margin bile duct #2
C: piece of xiphoid
D: gallbladder
E: right hepatic lobe
F: portal vein bifurcation

CLINICAL HISTORY:

Liver cancer. Prior outside slide review demonstrated likely hepatocellular carcinoma. *Note: Tissue taken for research*

INTRAOPERATIVE CONSULTATION (Frozen Section):

[page 4 of 5]
A: Positive for carcinoma. Read back received from
B: Negative for carcinoma. Read back received from

GROSS DESCRIPTION:

A: The specimen (received without fixative for frozen section analysis, labeled with the patient's name, medical record number and "distal margin bile duct") consists of a single piece of tan-brown fibrous soft tissue measuring 1.6 x 1.3 x 0.3 cm. The specimen is submitted entirely for frozen section analysis. The frozen section control is transferred to cassette A1 for permanents.

B: The specimen (received without fixative for frozen section analysis, labeled with the patient's name, medical record number and "distal margin bile duct #2") consists of an oriented single fragment of tan-yellow soft tissue measuring 2.0 x 1.5 x 1.0 cm. The specimen is oriented per the surgeon with a stitch on the true margin. The specimen is entirely submitted for frozen section analysis. The frozen section control is transferred to cassette B1 for permanents.

C: The specimen (received in formalin, labeled with the patient's name, medical record number and "piece of xiphoid") consists of a single piece of bone measuring 2.6 x 2.1 x 0.6 cm with attached tan-yellow lobulated adipose tissue. The specimen is entirely submitted in cassette C1 after decalcification.

D: The specimen (received in formalin, labeled with the patient's name, medical record number and "gallbladder") consists of a cholecystectomy measuring 7.0 x 3.1 x 1.0 cm. The serosa is smooth, tan-white and free of adhesions. The hepatic bed is roughened, tan and with cautery artifact. The cystic duct measures 0.3 cm in diameter at the margin of excision. The pliable wall thickness measures 0.3 cm on average. The lumen is filled with a small amount of green bile and no calculi. The mucosa is velvety and mildly bile stained. No masses or lesions are noted grossly. Representative sections are submitted in cassette D1.

E: The specimen (received in formalin, labeled with the patient's name, medical record number and "right hepatic lobe") consists of a 646 g partial hepatectomy consisting of right lobe measuring 13.5 x 12.0 x 6.0 cm. There is an attached segment of extrahepatic bile duct measuring 5.0 x 3.0 x 2.0 cm which has been oriented per the surgeon with a long black silk indicating left duct orifice and short stitch on distal bile duct. The specimen was inked during frozen section analysis with blue ink indicating the surgical resection margin and green ink on the capsule. A blue stitch has been applied at the area of possible attached diaphragm at the superior aspect of the specimen. The distal bile duct margin is inked orange. The bile duct is serially sectioned from distal to proximal to reveal a markedly dilated (1.0 cm in diameter) lumen filled with soft tan-white friable tumor, extending the length of the bile duct up to the left duct orifice. The tumor appears confined within the lumen of the bile duct with no direct extension between liver parenchyma and bile duct. The liver is serially sectioned to reveal an ill-defined white firm mass measuring 7.5 x 7.0 x 4.0 cm extending from the superior to mid aspect of the specimen and abutting the green and blue-inked surfaces. Additionally, there is a cystic space measuring 2.0 x 2.0 x 1.0 cm in the area underlying the diaphragm filled with green-yellow soft material. The remainder of the liver parenchyma is remarkable for diffuse cirrhosis without other masses or lesions. Representative sections are submitted per cassette summary.

Cassette Summary:

E1-7: bile duct serially sectioned from distal to proximal (E1 = distal)
E8: left duct orifice with surrounding liver
E9: mass to blue surgical resection margin
E10: mass to green capsule
E11-12: additional sections of mass
E13: cystic space underlying diaphragm

[page 5 of 5]
E14: mass to uninvolved liver
E15: uninvolved liver
E16: additional section of mass

F: The specimen (received in formalin, labeled with the patient's name, medical record number and "portal vein bifurcation") consists of a single piece of white-tan to tan-brown soft tissue measuring 3.3 x 1.3 x 0.5 cm. There are no lesions identified grossly. A representative section of the hepatic vein is submitted in cassette F1.

CONFIDENTIAL HEALTH INFORMATION: Health Care information is personal and sensitive information. If it is being faxed to you it is done so under appropriate authorization from the patient or under circumstances that do not require patient authorization. You, the recipient, are obligated to maintain it in a safe, secure and confidential manner. Re-disclosure without additional patient consent or as permitted by law is prohibited. Unauthorized re-disclosure or failure to maintain confidentiality could subject you to penalties described in federal and state law. If you have received this report or facsimile in error, please notify the [redacted] immediately and destroy the received document(s).

Criteria:	W 12/12/13	Yes	No

Source: NCI Genomic Data Commons file 95a3e80e-3468-4e1c-bdf6-a82948337291 (TCGA-2V-A95S.BE263DC7-2250-42E2-8AD6-D99A6DF679B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).